Surgical pathology report (de-identified scan), TCGA case TCGA-32-2638, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-2638-01A (Primary Tumor).

[page 1 of 2]
NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Brain tumor
2. Right temporal tumor

GBM
Control

CLINICAL DIAGNOSIS:

Brain tumor, right temporal tumor

TCGA-32-2638

GROSS DESCRIPTION:

1. Received fresh for frozen section labeled with the patient's name and "brain tumor" are three red-tan soft tissue fragments aggregating to 0.5 x 0.3 x 0.2 cm. A smear is performed with the remainder frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

EDEMATOUS WHITE MATTER WITH REACTIVE VASCULAR CHANGES.

The specimen is subsequently re-submitted for permanent sections.

2. Received fresh for frozen section labeled with the patient's name and "right temporal tumor" are multiple red-tan soft tissue fragments aggregating to 1.0 x 1.0 x 0.2 cm. A smear is performed with the remainder frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

GLIOBLASTOMA.

The specimen is subsequently re-submitted for permanent sections.

MICROSCOPIC DESCRIPTION:

1. Microscopic examination reveals cortical gray matter and underlying white matter. The white matter appears edematous and demonstrates scattered reactive astrocytes. The blood vessels appear thickened and many demonstrate hyalinized walls. A definitive neoplastic population is not seen.

2. Microscopic examination reveals an infiltrating glioma. The neoplasm appears hypercellular. The tumor cells diffusely infiltrate the brain parenchyma. They demonstrate moderate cytologic atypia. Morphologically the tumor cells exhibit elongated to oval nuclei with prominent fibrillary processes. Mitotic figures are prevalent. Microvascular proliferation is readily identified.

DIAGNOSIS:

(PROVISIONAL):

1. BRAIN TUMOR, BIOPSY AND RESECTION:
EDEMATOUS WHITE MATTER WITH REACTIVE FEATURES.
2. RIGHT TEMPORAL TUMOR, BIOPSY:
GLIOBLASTOMA, PENDING REVIEW OF ADDITIONAL SECTIONS.

[page 2 of 2]
ADDENDUM NEUROPATHOLOGY REPORT

ADDENDUM DISCUSSION:

ADDENDUM SPECIMEN SOURCE:

- 1-2. See original report.
2. Right temporal tumor - perm

ADDENDUM GROSS DESCRIPTION:

- 1-2. See original report.

3. Received in formalin labeled with the patient's name and "right temple tumor" are multiple tan-brown soft tissue fragments admixed with blood clots aggregating to 4.0 x 2.5 x 2.0 cm. The specimen is serially sectioned with representative sections submitted in two cassettes.

ADDENDUM MICROSCOPIC DESCRIPTION:

1. See original report.

3. Microscopic examination reveals a diffusely infiltrating high grade glial neoplasm. The tumor cells demonstrate moderate cytologic atypia. Occasional cells exhibit more marked atypical features. In some areas, the tumor cells appear spindle-like and demonstrate a sarcomatous growth pattern. Microvascular proliferation is robust. Numerous mitotic figures are seen. The malignant astrocytes demonstrate focal areas of perineuronal satellitosis. Early necrosis is identified. Pseudopalisading necrosis is not seen. There is a background of acute hemorrhage.

The neoplastic cells are immunoreactive for GFAP. They are negative for epithelial membrane antigen. They do not demonstrate collagen production and a permanent reticulin network is not seen. Tumor cells demonstrate patchy nuclear positivity for MGMT, but the overall positivity rate is less than 25%. Numerous MIB-1 reactive cells are present with a labeling index of greater than 25%.

ADDENDUM DIAGNOSIS:

1. BRAIN TUMOR, BIOPSY AND RESECTION:
EDEMATOUS WHITE MATTER WITH REACTIVE FEATURES.
- 2, 3. TEMPORAL TUMOR, RESECTION:

ADDENDUM DIAGNOSIS:

GLIOBLASTOMA (WHO GRADE 4).

Source: NCI Genomic Data Commons file 43e78958-4ae9-4c06-ba31-3c137ae18369 (TCGA-32-2638.ED601144-2884-4D75-886C-EAAAB49A6C33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).